Gene-level copy-number profile of tumor specimen TCGA-CS-5393-01A from TCGA case TCGA-CS-5393, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 39.5 years (14,418 days).
Specimen TCGA-CS-5393-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.75cd1945-9e65-4945-b754-49ab0146d9f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-5393-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d06a57c7-dbff-4f2a-9e61-3d247e4048ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 3,407; copy number 2: 54,184; copy number 3: 599; copy number 4: 524; copy number 5: 343; copy number 6: 747.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-5393-01A-01D-1466-01): tumor purity 0.55, ploidy 4.13, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,090 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:7,640,752–8,004,053, 1 gene, copy number 5 (within-gene range 1–5): AC007161.3.
- chr7:7,906,519–8,262,687, 7 genes, copy number 5 (within-gene range 1–6): RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1.
- chr7:8,262,233–8,939,369, 5 genes, copy number 5–6 (within-gene range 1–6): AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1.
- chr7:9,614,978–9,769,513, 3 genes, copy number 6 (within-gene range 3–6): GAPDHP68, AC060834.2, PER3P1.
- chr7:12,726,152–13,751,920, 1 gene, copy number 6 (within-gene range 1–6): AC011287.1.
- chr7:13,339,201–55,344,958, 694 genes, copy number 6 (broad region; genes not listed).
- chr8:106,697,427–108,626,767, 21 genes, copy number 5 (within-gene range 3–5): TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2.
- chr10:2,724,819–3,400,180, 16 genes, copy number 5: AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1.
- chr10:4,384,246–24,547,848, 340 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr10:25,158,072–25,176,276, 1 gene, copy number 5 (within-gene range 3–5): GPR158-AS1.
- chr10:25,244,061–25,244,854, 1 gene, copy number 5: AL354976.1.

Autosomal genes at a single copy (total copy number 1): 997. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
